Gene-level copy-number profile of tumor specimen TCGA-CR-7374-01A from TCGA case TCGA-CR-7374, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 67.2 years (24,558 days).
Specimen TCGA-CR-7374-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.869444eb-b54c-4cea-a99a-66b14cae537f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7374-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af0b19c2-29b5-4b90-a65b-bde0c27dcdac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 24,222; copy number 2: 31,992; copy number 3: 2,519; copy number 4: 247; copy number 5: 608; copy number 7: 98; copy number 9: 125.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7374-01A-11D-2010-01): tumor purity 0.65, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:47,764,954–48,046,216, 3 genes: LINC00648, AL121576.1, AL359212.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 831 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:145,824,257–174,378,005, 432 genes, copy number 5–7 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 7: RN7SKP40.
- chr3:176,113,702–185,153,060, 184 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:36,378,069–38,704,855, 63 genes, copy number 5 (broad region; genes not listed).
- chr15:24,101,827–24,823,365, 1 gene, copy number 5 (within-gene range 3–5): PWRN1.
- chr15:24,206,784–28,405,033, 150 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
